Somatic mutation profile of tumor specimen ALCH-AE1W-TTP1-A (aliquot ALCH-AE1W-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-AE1W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,712 days).
Specimen ALCH-AE1W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b991339-0414-4360-8bb2-1e413be2e300.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE1W-NB1-A (Blood Derived Normal), aliquot ALCH-AE1W-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64ba603b-10a3-449e-b63f-f2d82a6ea8fa

The open-access MAF lists 309 somatic variants for this specimen: 197 protein-altering or splice-affecting, 82 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 82, Nonsense Mutation 14, Intron 10, 5'UTR 7, Splice Site 5, 3'UTR 5, RNA 5, 5'Flank 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 70/722 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ADAM2 | c.1098G>T p.Q366H | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as COSV55866653; called by muse, mutect2
- ANAPC1 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 40/1416 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1285246821; called by muse, mutect2
- APOO | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | catalogued as rs759130534; called by muse, mutect2
- ARID1A | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 36/645 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV61374200, COSV61375315; called by muse, mutect2
- ATG4A | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV58965898; called by muse, mutect2
- B3GNT3 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as COSV59438521; called by muse, mutect2, varscan2
- BTBD9 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 31/752 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1405870898, COSV58422636; called by muse, mutect2
- CCN1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs867795349; called by muse, mutect2
- CDCP1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 114/873 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs374678265; called by muse, mutect2, varscan2
- CDNF | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 59/898 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65805709; called by muse, mutect2
- CFAP54 | c.5196G>T p.L1732F | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV100732910, COSV61572398; called by muse, mutect2, varscan2
- CHD8 | c.6518C>T p.S2173L (on ENST00000646647 / NM_001170629.2; = p.S1894L on NM_020920.4) | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs781575717, CM145746; called by muse, mutect2
- CLIC5 | c.613G>T p.G205* (on ENST00000185206 / NM_001370649.1; = p.G46* on NM_016929.5) | Nonsense Mutation (SNP) | VAF 41/480 reads (9%) | catalogued as COSV51766253; called by muse, mutect2
- CLTRN | c.567G>C p.M189I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66711964; called by muse, mutect2
- CRELD1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 74/929 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.313); catalogued as rs750351756; called by muse, mutect2
- DCAF12L2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 18/505 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV63583931; called by muse, mutect2
- EIF4G1 | c.1357C>T p.Q453* (on ENST00000346169 / NM_198241.3; = p.Q257* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 27/287 reads (9%) | catalogued as COSV59990178; called by muse, mutect2
- EPHA5 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 89/1385 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99900386, COSV99902470; called by muse, mutect2
- ESPNL | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780626181, COSV58039115; called by muse, mutect2, varscan2
- GP1BB | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV100820482; called by muse, mutect2
- GPR6 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 36/711 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV51573775; called by muse, mutect2
- HAPLN4 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1024155752; called by muse, mutect2
- HECTD1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 50/870 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs1169523562, COSV101237297; called by muse, mutect2
- HOXD12 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs766187461, COSV66832731; called by muse, mutect2, varscan2
- HS3ST4 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 50/715 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100502671; called by muse, mutect2
- IL22RA2 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 76/728 reads (10%) | catalogued as rs762290472, COSV99760835; called by muse, mutect2, varscan2
- IMPG2 | c.3603G>T p.Q1201H | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99516455; called by muse, mutect2, varscan2
- ITGAX | c.348C>A p.C116* | Nonsense Mutation (SNP) | VAF 24/191 reads (13%) | catalogued as rs756474155; called by muse, varscan2
- LRP1B | c.10908G>T p.Q3636H | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs950938230; called by muse, mutect2
- MAGEB2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100975558; called by muse, mutect2
- MFN2 | c.475-1G>T p.X159_splice | Splice Site (SNP) | VAF 29/786 reads (4%) | catalogued as CS083949, CS1110356; called by muse, mutect2
- MSH5 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 58/675 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs764436774; called by muse, mutect2
- NCAPH2 | c.354C>T p.F118= | Splice Region (SNP) | VAF 20/380 reads (5%) | catalogued as rs972091586; called by muse, mutect2
- NFKBIE | c.722T>A p.V241E (on ENST00000275015; = p.V102E on NM_004556.3) | Missense Mutation (SNP) | VAF 31/538 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs776457921; called by muse, mutect2
- OCRL | c.1773C>A p.N591K | Missense Mutation (SNP) | VAF 33/556 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs137853844, CM097490; ClinVar: not provided; called by muse, mutect2
- OR2G3 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344613375, COSV60682777, COSV60682889; called by muse, mutect2
- OTOG | c.6014C>T p.S2005L | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771329383; called by muse, mutect2
- PEG3 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 100/966 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99688115; called by muse, mutect2
- POTEI | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 174/2006 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs1221592814; called by muse, mutect2
- ROBO4 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as rs1194072424; called by muse, mutect2
- SF3B1 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764445898; called by muse, mutect2, varscan2
- SLAMF7 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 68/656 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs777613712; called by muse, mutect2, varscan2
- SNAP25 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 62/842 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54771039; called by muse, mutect2
- ST18 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 30/781 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1056770133; called by muse, mutect2
- STAG2 | c.2167G>T p.G723* | Nonsense Mutation (SNP) | VAF 21/303 reads (7%) | catalogued as COSV54360882; called by muse, mutect2
- TIMP4 | c.146G>C p.R49P | Missense Mutation (SNP) | VAF 72/560 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452503534, COSV55138752; called by muse, mutect2, varscan2
- TMC4 | c.614C>T p.S205L (on ENST00000617472 / NM_001145303.3; = p.S199L on NM_144686.4) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs779701401, COSV55475199; called by muse, mutect2
- UBR2 | c.4100G>T p.R1367M | Missense Mutation (SNP) | VAF 20/549 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV65751497; called by muse, mutect2
- VAT1 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1390244149; called by muse, mutect2
- ZNF229 | c.992G>T p.R331I | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.14); catalogued as COSV52161315; called by muse, mutect2
- ZNF536 | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV100834703; called by muse, mutect2
- ZNF653 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1182218001; called by muse, mutect2
- ABCA12 | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 114/887 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ABCA2 | c.6064G>T p.G2022* (on ENST00000614293; = p.G1992* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2
- ABCC12 | c.3664A>T p.T1222S | Missense Mutation (SNP) | VAF 41/457 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.044); called by muse, mutect2
- AC020907.6 | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2
- ACACA | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 42/1024 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- ACIN1 | c.1385G>T p.R462M | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ACKR3 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 94/808 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AGPAT5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ANK2 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 44/986 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARID1A | c.5866G>T p.E1956* | Nonsense Mutation (SNP) | VAF 26/435 reads (6%) | called by muse, mutect2
- ASPG | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.077); called by muse, mutect2
- ASRGL1 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 28/850 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- ASTN1 | c.3779C>A p.P1260H | Missense Mutation (SNP) | VAF 56/1075 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- ATXN3L | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BAZ1A | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2
- BPIFA3 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2
- BRF1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- BUB1 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1orf167 | c.3895A>G p.S1299G | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- CCNB1IP1 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- CD151 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 55/490 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH9 | c.1850T>G p.V617G | Missense Mutation (SNP) | VAF 90/691 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- CEP89 | c.281C>G p.A94G | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CES1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 121/2003 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST8 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 43/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CLCN5 | c.1523C>A p.A508E | Missense Mutation (SNP) | VAF 54/1046 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLDN7 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNKSR2 | c.2314A>T p.I772F | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- CNP | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2
- COL18A1 | c.2040G>T p.E680D (on ENST00000359759 / NM_130444.3; = p.E445D on NM_030582.4) | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- CRACD | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- CRAT | c.1355A>T p.Y452F | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); called by muse, mutect2
- CSMD1 | c.4576C>G p.Q1526E (on ENST00000520002; = p.Q1525E on NM_033225.6) | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2
- CT83 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL3 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- CYP11A1 | c.713A>C p.Y238S | Missense Mutation (SNP) | VAF 44/723 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.021); called by muse, mutect2
- DBH | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- DDTL | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DDX55 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 51/958 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- DGKI | c.568T>A p.C190S | Missense Mutation (SNP) | VAF 132/1138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DGKI | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 138/1160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DPPA2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DPYSL5 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 63/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EDA2R | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2
- EEA1 | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 56/534 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EID1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 56/706 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EPC1 | c.867G>C p.Q289H | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- ERVV-2 | c.934A>T p.N312Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- F8 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2
- FANCC | c.250+1G>T p.X84_splice | Splice Site (SNP) | VAF 17/233 reads (7%) | called by muse, mutect2
- FBN2 | c.3163G>T p.G1055W | Missense Mutation (SNP) | VAF 133/899 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GAB4 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.881); called by muse, mutect2
- GALNT3 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 58/610 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.107); called by muse, mutect2
- GFRA1 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR101 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIA3 | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 23/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- GZMB | c.727A>C p.T243P | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- GZMB | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 39/752 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAUS7 | c.504G>T p.R168S | Missense Mutation (SNP) | VAF 33/463 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- HCN4 | c.2542C>G p.Q848E | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.077); called by muse, mutect2
- HUWE1 | c.10797G>T p.E3599D | Missense Mutation (SNP) | VAF 48/692 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- IGHV3-35 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- KCNH2 | c.2792C>A p.P931Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- KIAA0319 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIF4B | c.2228T>A p.V743E | Missense Mutation (SNP) | VAF 130/1094 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- LMNA | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2
- LRP1 | c.10640G>A p.R3547H | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- LRP1B | c.5704G>T p.A1902S | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- LRRN3 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- MAGEA11 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2
- MAP1A | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 36/823 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MCC | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 82/631 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCUR1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 56/552 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- MFAP3 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 75/570 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MUC1 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 54/683 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- MUC12 | c.3954C>G p.H1318Q (on ENST00000379442; = p.H1175Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/1184 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.234); called by muse, mutect2
- MUC16 | c.37337+1G>T p.X12446_splice | Splice Site (SNP) | VAF 53/494 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.8267C>A p.T2756N | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- MUC5B | c.9524T>A p.V3175E | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- MYH8 | c.4325G>T p.C1442F | Missense Mutation (SNP) | VAF 56/986 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- NAT16 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 64/426 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- NDUFS4 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 33/671 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- NELL1 | c.994del p.R332Dfs*18 | Frame Shift Del (DEL) | VAF 93/880 reads (11%) | called by mutect2, pindel, varscan2
- NODAL | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 30/994 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2
- NOM1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NR2C2AP | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- NR2E1 | c.777C>A p.N259K | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NRDE2 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- OAT | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 68/906 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- OR51V1 | c.85T>A p.W29R | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OTOG | c.3760C>A p.P1254T | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.35C>G p.P12R (on ENST00000547103; = p.P3R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2
- PADI3 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 58/602 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGB6 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 23/793 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PCSK5 | c.4613G>T p.C1538F | Missense Mutation (SNP) | VAF 66/678 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PGR | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- PLCL2 | c.1962C>G p.S654R (on ENST00000615277 / NM_001144382.2; = p.S528R on NM_015184.5) | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLTP | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 55/654 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, mutect2
- POLR2B | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); called by muse, mutect2
- POP1 | c.2563G>C p.A855P | Missense Mutation (SNP) | VAF 37/884 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2
- PRKCD | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 32/444 reads (7%) | called by muse, mutect2
- PRODH2 | c.799C>A p.L267M (on ENST00000301175; = p.L191M on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2
- PTGIR | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.1523C>A p.T508N | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTPRZ1 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- RAB8B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2
- RABGAP1L | c.499C>T p.Q167* (on ENST00000489615 / NM_001243765.2; = p.Q50* on NM_001243764.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/335 reads (12%) | called by muse, mutect2, varscan2
- RANBP2 | c.8023G>A p.E2675K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBBP4 | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- REV3L | c.5297A>T p.Q1766L | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RHPN1 | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2
- RP1 | c.5695G>T p.G1899C | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- RPP25 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.13589G>T p.G4530V | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.486); called by muse, mutect2
- SCN1A | c.5122G>C p.E1708Q (on ENST00000303395 / NM_001202435.3; = p.E1697Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/824 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.401); called by muse, mutect2
- SEC61A1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 37/687 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2
- SERPINE1 | c.506-2A>T p.X169_splice | Splice Site (SNP) | VAF 77/467 reads (16%) | called by muse, mutect2, varscan2
- SGCZ | c.424+1G>T p.X142_splice | Splice Site (SNP) | VAF 22/451 reads (5%) | called by muse, mutect2
- SIGLEC6 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); called by muse, mutect2
- SLC24A2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 91/789 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.096); called by muse, mutect2
- SMCHD1 | c.4144T>G p.L1382V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2
- SOX2 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 170/1068 reads (16%) | called by muse, mutect2, varscan2
- SP5 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- SPTB | c.2287C>A p.H763N | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SYT16 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2
- TEX2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 63/1035 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2
- TM6SF1 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 30/419 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2
- TRIM58 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 44/850 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.105); called by muse, mutect2
- TRPM3 | c.3660G>C p.E1220D (on ENST00000357533 / NM_001366142.2; = p.E1075D on NM_020952.6) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TTLL2 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 47/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBA1 | c.1995G>T p.Q665H | Missense Mutation (SNP) | VAF 84/1130 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2
- UHRF1BP1 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 17/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC13A | c.1840C>G p.H614D | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- URGCP-MRPS24 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT tolerated, low confidence (0.35); called by muse, mutect2, varscan2
- USH2A | c.8902A>T p.T2968S | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- VPS41 | c.809A>T p.Y270F | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ZFP91 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ZFYVE26 | c.6034C>A p.L2012M | Missense Mutation (SNP) | VAF 98/1262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZIC5 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 17/625 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF84 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- ZP4 | c.1114A>T p.S372C | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZSCAN5A | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- ZSWIM1 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 35/584 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2
- ADRB3 | c.798C>T p.C266= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs994820991, COSV100800038; called by muse, mutect2
- AFM | c.1227C>A p.L409= | Silent (SNP) | VAF 15/239 reads (6%) | catalogued as COSV56922634; called by muse, mutect2
- AGAP1 | c.657G>A p.E219= | Silent (SNP) | VAF 38/524 reads (7%) | called by muse, mutect2
- ANKRD30A | c.1083T>A p.I361= (on ENST00000611781; = p.I305= on NM_052997.2) | Silent (SNP) | VAF 28/405 reads (7%) | catalogued as COSV64609785; called by muse, mutect2
- ANKS6 | c.2436G>A p.L812= | Silent (SNP) | VAF 48/667 reads (7%) | catalogued as rs1461637815; called by muse, mutect2
- AUTS2 | c.3465G>A p.L1155= | Silent (SNP) | VAF 20/519 reads (4%) | catalogued as COSV61426855; called by muse, mutect2
- BEX2 | c.183C>A p.P61= | Silent (SNP) | VAF 46/556 reads (8%) | called by muse, mutect2
- BPHL | c.720C>T p.H240= | Silent (SNP) | VAF 69/722 reads (10%) | catalogued as rs553521784, COSV66743002; called by muse, mutect2
- BTAF1 | c.4479C>T p.H1493= | Silent (SNP) | VAF 12/318 reads (4%) | called by muse, mutect2
- C1orf68 | c.540G>A p.V180= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- C2CD4D | c.852C>T p.P284= | Silent (SNP) | VAF 15/364 reads (4%) | called by muse, mutect2
- CBFB | c.24G>A p.Q8= | Silent (SNP) | VAF 28/432 reads (6%) | catalogued as COSV52002755; called by muse, mutect2
- CBX6 | c.579G>T p.G193= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CCDC120 | c.942C>T p.G314= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- CCDC85C | c.690C>T p.P230= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- CELF5 | c.1269C>T p.F423= | Silent (SNP) | VAF 22/344 reads (6%) | catalogued as rs746421083, COSV53013478; called by muse, mutect2
- CLCN5 | c.1524A>G p.A508= | Silent (SNP) | VAF 54/1038 reads (5%) | called by muse, mutect2
- CNGA2 | c.1173C>A p.A391= | Silent (SNP) | VAF 46/490 reads (9%) | catalogued as COSV104395842; called by muse, mutect2
- CNKSR2 | c.1764A>G p.S588= | Silent (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- CRIP2 | c.537T>C p.Y179= | Silent (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- CSF2RB | c.906C>A p.T302= | Silent (SNP) | VAF 28/540 reads (5%) | called by muse, mutect2
- DHX35 | c.1230C>G p.A410= | Silent (SNP) | VAF 34/660 reads (5%) | called by muse, mutect2
- DUS1L | c.129C>G p.L43= | Silent (SNP) | VAF 19/336 reads (6%) | called by muse, mutect2
- EFHC2 | c.2220G>A p.L740= | Silent (SNP) | VAF 19/599 reads (3%) | called by muse, mutect2
- EPHX3 | c.987C>T p.A329= | Silent (SNP) | VAF 58/653 reads (9%) | called by muse, mutect2
- FAM171B | c.1755C>A p.T585= | Silent (SNP) | VAF 72/719 reads (10%) | called by muse, mutect2
- FBLL1 | c.486C>A p.G162= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs955911349; called by muse, mutect2, varscan2
- FGD5 | c.3930G>A p.L1310= | Silent (SNP) | VAF 28/305 reads (9%) | catalogued as COSV53239209; called by muse, mutect2
- FLG | c.5730A>T p.T1910= | Silent (SNP) | VAF 78/820 reads (10%) | catalogued as rs186931716; called by muse, mutect2
- FOXC2 | c.789G>A p.A263= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- FREM3 | c.2392C>A p.R798= | Silent (SNP) | VAF 35/685 reads (5%) | called by muse, mutect2
- FSIP2 | c.17232C>G p.A5744= | Silent (SNP) | VAF 13/80 reads (16%) | called by muse, varscan2
- GOLM2 | c.48C>T p.L16= | Silent (SNP) | VAF 23/226 reads (10%) | catalogued as rs372220445, COSV100247859; called by muse, mutect2
- GRM5 | c.177G>T p.A59= | Silent (SNP) | VAF 148/1221 reads (12%) | called by muse, mutect2, varscan2
- HTR1E | c.957C>T p.Y319= | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as rs147060180; called by muse, mutect2
- IFRD1 | c.546T>A p.A182= | Silent (SNP) | VAF 36/814 reads (4%) | called by muse, mutect2
- INPP5F | c.1866C>T p.A622= | Silent (SNP) | VAF 28/536 reads (5%) | called by muse, mutect2
- JAKMIP1 | c.2067C>A p.T689= | Silent (SNP) | VAF 41/400 reads (10%) | catalogued as COSV68952800; called by muse, mutect2
- KCNT2 | c.1725C>A p.S575= | Silent (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- KCTD3 | c.2166G>A p.L722= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- KIF18A | c.1926A>G p.G642= | Silent (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- KRTAP10-5 | c.672C>T p.L224= | Silent (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- L3MBTL1 | c.2085A>G p.S695= (on ENST00000418998 / NM_001377303.1; = p.S605= on NM_015478.7) | Silent (SNP) | VAF 21/352 reads (6%) | catalogued as rs758348482; called by muse, mutect2
- MAPK8IP2 | c.144C>T p.L48= | Silent (SNP) | VAF 19/361 reads (5%) | catalogued as COSV99151398; called by muse, mutect2
- NACC2 | c.195C>T p.S65= | Silent (SNP) | VAF 18/336 reads (5%) | catalogued as rs947074927; called by muse, mutect2
- NOTCH3 | c.2700C>T p.T900= | Silent (SNP) | VAF 22/408 reads (5%) | catalogued as rs1325188788; called by muse, mutect2
- NWD2 | c.4734C>T p.Y1578= | Silent (SNP) | VAF 29/348 reads (8%) | called by muse, mutect2
- OAF | c.177C>T p.L59= | Silent (SNP) | VAF 17/328 reads (5%) | called by muse, mutect2
- OAS2 | c.933G>A p.L311= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs1565994752; called by muse, mutect2
- OCRL | c.1020T>C p.A340= | Silent (SNP) | VAF 45/714 reads (6%) | called by muse, mutect2
- PCDH1 | c.519C>T p.I173= | Silent (SNP) | VAF 54/794 reads (7%) | called by muse, mutect2
- PCDHGB2 | c.1698G>T p.A566= | Silent (SNP) | VAF 80/546 reads (15%) | catalogued as rs376471858; called by muse, mutect2, varscan2
- PLVAP | c.1266G>A p.K422= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs1281036864; called by muse, mutect2
- PLXNB2 | c.2694C>T p.L898= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- PNN | c.1170A>C p.L390= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- PPP2R5D | c.1197G>A p.V399= | Silent (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- PRMT7 | c.1725C>T p.S575= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs1015001881; called by muse, mutect2
- RASGRP2 | c.1146G>T p.L382= | Silent (SNP) | VAF 67/668 reads (10%) | catalogued as rs1436968076; called by muse, mutect2, varscan2
- RYR2 | c.4542C>A p.A1514= | Silent (SNP) | VAF 48/681 reads (7%) | called by muse, mutect2
- SERPINA6 | c.844C>A p.R282= | Silent (SNP) | VAF 50/568 reads (9%) | called by muse, mutect2
- SFXN5 | c.897C>T p.F299= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as rs567169280, COSV55586820; called by muse, mutect2, varscan2
- SH3TC2 | c.18C>T p.C6= | Silent (SNP) | VAF 91/835 reads (11%) | catalogued as COSV60463593; called by muse, mutect2, varscan2
- SIPA1L1 | c.120G>T p.R40= | Silent (SNP) | VAF 30/443 reads (7%) | called by muse, mutect2
- SKIDA1 | c.2598G>T p.P866= | Silent (SNP) | VAF 20/668 reads (3%) | called by muse, mutect2
- STK26 | c.15G>T p.P5= | Silent (SNP) | VAF 43/662 reads (6%) | called by muse, mutect2
- STK36 | c.3126C>T p.L1042= | Silent (SNP) | VAF 16/370 reads (4%) | catalogued as rs941935816; called by muse, mutect2
- SYT4 | c.345T>C p.P115= | Silent (SNP) | VAF 17/491 reads (3%) | called by muse, mutect2
- TADA1 | c.528C>T p.V176= | Silent (SNP) | VAF 20/690 reads (3%) | catalogued as rs1466249701; called by muse, mutect2
- THEMIS2 | c.1618C>A p.R540= | Silent (SNP) | VAF 20/512 reads (4%) | catalogued as COSV61077639; called by muse, mutect2
- THOC5 | c.195G>C p.L65= | Silent (SNP) | VAF 21/394 reads (5%) | called by muse, mutect2
- TNKS1BP1 | c.1965G>T p.R655= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- TSPYL6 | c.1041C>T p.I347= | Silent (SNP) | VAF 40/398 reads (10%) | called by muse, mutect2
- TUT7 | c.3336G>A p.L1112= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- VAT1 | c.510C>T p.L170= | Silent (SNP) | VAF 52/945 reads (6%) | catalogued as rs148333397; called by muse, mutect2
- ZBTB6 | c.897G>A p.L299= | Silent (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- ZEB2 | c.2064G>T p.V688= | Silent (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
- ZFP92 | c.963G>T p.A321= | Silent (SNP) | VAF 21/298 reads (7%) | catalogued as rs572661916; called by muse, mutect2
- ZNF358 | c.381C>T p.L127= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- ZNF444 | c.780C>T p.Y260= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- ZNF536 | c.1257C>G p.S419= | Silent (SNP) | VAF 22/245 reads (9%) | called by muse, mutect2
- ZNF835 | c.288C>T p.D96= | Silent (SNP) | VAF 56/796 reads (7%) | called by muse, mutect2
- ZSCAN5A | c.1239G>A p.T413= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as rs543909314, COSV54231348; called by muse, mutect2
- BCAN | c.2210-41C>T | Intron (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- BTN2A2 | c.980-138G>T | Intron (SNP) | VAF 60/728 reads (8%) | called by muse, mutect2
- C1QB | c.*45C>T | 3'UTR (SNP) | VAF 20/284 reads (7%) | catalogued as rs551075438, COSV100152819; called by muse, mutect2
- C8orf74 | c.-17A>T | 5'UTR (SNP) | VAF 31/868 reads (4%) | called by muse, mutect2
- CTSL3P | n.530G>C | RNA (SNP) | VAF 53/567 reads (9%) | called by muse, mutect2
- DNAH14 | c.6033+2176G>T | Intron (SNP) | VAF 22/810 reads (3%) | called by muse, mutect2
- EML6 | c.-1C>A | 5'UTR (SNP) | VAF 16/378 reads (4%) | called by muse, mutect2
- FLNA | c.1828+27C>A | Intron (SNP) | VAF 42/558 reads (8%) | called by muse, mutect2
- FRMD8P1 | n.1213A>G | RNA (SNP) | VAF 18/267 reads (7%) | called by muse, mutect2
- GABRE | c.784+269G>T | Intron (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- HIP1R | chr12:122834955 G>T | 5'Flank (SNP) | VAF 40/486 reads (8%) | called by muse, mutect2
- IL10RA | c.*316T>A | 3'UTR (SNP) | VAF 77/767 reads (10%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.855G>T | RNA (SNP) | VAF 71/717 reads (10%) | called by muse, mutect2, varscan2
- KRT14 | c.-2C>G | 5'UTR (SNP) | VAF 27/503 reads (5%) | called by muse, mutect2
- LAD1 | c.*55C>T | 3'UTR (SNP) | VAF 39/622 reads (6%) | catalogued as rs1369410717; called by muse, mutect2
- MATN2 | c.-16C>G | 5'UTR (SNP) | VAF 16/414 reads (4%) | catalogued as rs936423497; called by muse, mutect2
- MRGPRX3 | chr11:18140567 T>C | 3'Flank (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.781C>T | RNA (SNP) | VAF 31/629 reads (5%) | catalogued as rs750463315; called by muse, mutect2
- PIAS3 | c.-30_-27del | 5'UTR (DEL) | VAF 50/389 reads (13%) | called by mutect2, pindel*, varscan2
- PLEK | c.*1A>G | 3'UTR (SNP) | VAF 28/328 reads (9%) | catalogued as rs1445700035; called by muse, mutect2
- SCFD1 | c.613+577G>A | Intron (SNP) | VAF 38/618 reads (6%) | called by muse, mutect2
- SCNN1A | c.-55+9G>A | Intron (SNP) | VAF 30/597 reads (5%) | called by muse, mutect2
- SHROOM4 | c.*600C>A | 3'UTR (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- SINHCAF | c.-21+870del | Intron (DEL) | VAF 56/485 reads (12%) | called by mutect2, pindel, varscan2
- SP5 | chr2:170713864 G>A | 5'Flank (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- STAR | c.178+51G>A | Intron (SNP) | VAF 18/466 reads (4%) | called by muse, mutect2
- UBBP4 | n.754C>G | RNA (SNP) | VAF 120/1338 reads (9%) | catalogued as rs1339110900; called by muse, mutect2
- VSX2 | c.-4G>A | 5'UTR (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- ZNF449 | c.-1G>T | 5'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- ZNF720 | c.226+10222G>T | Intron (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
